Somatic mutation profile of tumor specimen C3N-00577-03 (aliquot CPT0069170009) from CPTAC case C3N-00577, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 72.7 years (26,555 days).
Specimen C3N-00577-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2fc4a0f7-0e3c-4b9b-a3a8-ca46dcba619b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00577-71 (Blood Derived Normal), aliquot CPT0069270002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/16f7dbb3-baa4-41f9-9fe1-30e8ff0dec7a

The open-access MAF lists 61 somatic variants for this specimen: 32 protein-altering or splice-affecting, 22 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 22, Intron 4, Frame Shift Del 2, Splice Site 1, 5'Flank 1, RNA 1, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFF4 | c.1859C>A p.S620Y | Missense Mutation (SNP) | VAF 10/202 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1208947343; called by muse, mutect2
- C10orf90 | c.442G>A p.G148S | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.844); catalogued as rs774093912; called by muse, mutect2, varscan2
- DPH5 | c.557G>T p.R186L | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); catalogued as COSV59859843, COSV59860468; called by muse, mutect2, varscan2
- DR1 | c.516T>A p.D172E | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV64725888; called by muse, mutect2, varscan2
- GABRB1 | c.1264G>A p.G422R | Missense Mutation (SNP) | VAF 15/237 reads (6%) | SIFT tolerated (0.69); PolyPhen benign (0.005); catalogued as rs748097369, COSV54984293; called by muse, mutect2
- GDF10 | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 7/150 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs782581244; called by muse, mutect2
- MYO3B | c.706C>G p.L236V | Missense Mutation (SNP) | VAF 27/159 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs556789877; called by muse, mutect2, varscan2
- MYOM3 | c.1598C>A p.T533K | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.287); catalogued as COSV58392186; called by muse, mutect2
- AJM1 | c.2588C>T p.A863V | Missense Mutation (SNP) | VAF 16/153 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- CAPN6 | c.653T>A p.L218Q | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CDIP1 | c.341C>T p.T114I | Missense Mutation (SNP) | VAF 38/469 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.559); called by muse, mutect2
- CPA5 | c.818A>G p.N273S | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CRHR2 | c.619T>A p.C207S | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.926); called by muse, mutect2
- DRD4 | c.610C>T p.P204S | Missense Mutation (SNP) | VAF 86/526 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- GOLGA8J | c.115A>T p.N39Y | Missense Mutation (SNP) | VAF 34/436 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, varscan2
- GPD1 | c.17T>A p.V6D | Missense Mutation (SNP) | VAF 26/232 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LYST | c.2530A>G p.I844V | Missense Mutation (SNP) | VAF 15/316 reads (5%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2
- OTOP2 | c.458T>A p.F153Y | Missense Mutation (SNP) | VAF 16/326 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PBRM1 | c.4680+2T>C p.X1560_splice (on ENST00000296302 / NM_001366071.2; = p.X1453_splice on NM_018313.5) | Splice Site (SNP) | VAF 14/72 reads (19%) | called by muse, mutect2, varscan2
- RABGGTA | c.26C>A p.T9K | Missense Mutation (SNP) | VAF 19/205 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); called by muse, mutect2
- RDH13 | c.386G>T p.R129L (on ENST00000415061 / NM_001145971.2; = p.R58L on NM_138412.4) | Missense Mutation (SNP) | VAF 43/273 reads (16%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- RELN | c.8608C>T p.Q2870* | Nonsense Mutation (SNP) | VAF 19/169 reads (11%) | called by muse, mutect2, varscan2
- SHOX | c.766T>C p.S256P | Missense Mutation (SNP) | VAF 60/571 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- SLC25A16 | c.732A>T p.L244F | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.597); called by muse, varscan2
- SNAP91 | c.1748C>T p.A583V | Missense Mutation (SNP) | VAF 9/146 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, mutect2
- TBX5 | c.212del p.G71Afs*4 | Frame Shift Del (DEL) | VAF 56/455 reads (12%) | called by mutect2, pindel, varscan2
- TLE3 | c.88_101delinsT p.K30Cfs*29 | Frame Shift Del (DEL) | VAF 38/165 reads (23%) | called by pindel, varscan2*
- TLN1 | c.4118T>C p.V1373A | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.186); called by muse, mutect2
- TRIM26 | c.1334C>A p.S445Y | Missense Mutation (SNP) | VAF 36/460 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); called by muse, mutect2
- ZFR | c.83A>G p.Y28C | Missense Mutation (SNP) | VAF 45/352 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ZNF430 | c.1237T>C p.S413P | Missense Mutation (SNP) | VAF 13/158 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.013); called by muse, mutect2
- ZNF470 | c.1189T>A p.F397I | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- ANKRD39 | c.264T>G p.A88= | Silent (SNP) | VAF 88/419 reads (21%) | called by muse, mutect2, varscan2
- ATP6V1B1 | c.1482C>T p.I494= | Silent (SNP) | VAF 18/416 reads (4%) | called by muse, mutect2
- CLUH | c.2169A>G p.S723= (on ENST00000435359; = p.S762= on NM_015229.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/150 reads (17%) | called by muse, mutect2, varscan2
- CUX1 | c.57A>G p.V19= (on ENST00000292535 / NM_181552.4; = p.V30= on NM_001913.5) | Silent (SNP) | VAF 16/170 reads (9%) | catalogued as rs1278377019; called by muse, mutect2
- KIR3DL3 | c.57C>T p.P19= | Silent (SNP) | VAF 12/70 reads (17%) | called by muse, mutect2, varscan2
- KMT2E | c.4833C>T p.P1611= | Silent (SNP) | VAF 21/279 reads (8%) | catalogued as rs1243172763; called by muse, mutect2
- KRTAP4-9 | c.585C>G p.V195= | Silent (SNP) | VAF 20/250 reads (8%) | called by muse, mutect2
- LRAT | c.615T>C p.S205= | Silent (SNP) | VAF 15/194 reads (8%) | called by muse, mutect2
- OIT3 | c.312T>C p.A104= | Silent (SNP) | VAF 14/260 reads (5%) | called by muse, mutect2
- OR9K2 | c.463C>T p.L155= (on ENST00000305377; = p.L133= on NM_001005243.1) | Silent (SNP) | VAF 20/218 reads (9%) | called by muse, mutect2
- RGS20 | c.174G>A p.P58= | Silent (SNP) | VAF 25/212 reads (12%) | catalogued as COSV52020210; called by muse, mutect2, varscan2
- SETD1A | c.723C>A p.T241= | Silent (SNP) | VAF 42/488 reads (9%) | called by muse, mutect2
- SIGLECL1 | c.180C>T p.T60= | Silent (SNP) | VAF 45/309 reads (15%) | called by muse, mutect2, varscan2
- SIN3A | c.300G>A p.Q100= | Silent (SNP) | VAF 29/374 reads (8%) | catalogued as COSV64582507; called by muse, mutect2
- SLC6A12 | c.780T>C p.L260= | Silent (SNP) | VAF 24/364 reads (7%) | called by muse, mutect2
- TERT | c.3267C>T p.Y1089= | Silent (SNP) | VAF 22/444 reads (5%) | catalogued as rs759883263, COSV99716060; ClinVar: likely benign; called by muse, mutect2
- TIMM44 | c.438G>A p.K146= | Silent (SNP) | VAF 54/486 reads (11%) | catalogued as COSV54494255; called by muse, mutect2, varscan2
- TTC34 | c.2356C>T p.L786= | Silent (SNP) | VAF 12/191 reads (6%) | called by muse, mutect2
- TTLL10 | c.1323A>G p.E441= (on ENST00000379289 / NM_001130045.2; = p.E368= on NM_153254.3) | Silent (SNP) | VAF 10/227 reads (4%) | catalogued as COSV64959720; called by muse, mutect2
- USP34 | c.7800C>A p.A2600= | Silent (SNP) | VAF 23/85 reads (27%) | called by muse, mutect2, varscan2
- WDR81 | c.1098G>C p.L366= | Silent (SNP) | VAF 9/72 reads (13%) | called by muse, mutect2, varscan2
- ZNF721 | c.2469A>G p.K823= (on ENST00000338977; = p.K835= on NM_133474.4) | Silent (SNP) | VAF 10/182 reads (5%) | called by muse, mutect2
- COPZ2 | c.112-258C>T | Intron (SNP) | VAF 11/104 reads (11%) | called by muse, mutect2, varscan2
- GLRX | chr5:95823891 C>A | 5'Flank (SNP) | VAF 31/262 reads (12%) | catalogued as rs751794723; called by muse, mutect2, varscan2
- LINC00602 | n.1069G>C | RNA (SNP) | VAF 12/109 reads (11%) | called by muse, mutect2, varscan2
- MADCAM1 | c.667+1225C>T | Intron (SNP) | VAF 12/199 reads (6%) | called by muse, mutect2
- PELP1 | c.1068+53C>T | Intron (SNP) | VAF 53/432 reads (12%) | called by muse, mutect2, varscan2
- PIWIL1 | c.2469+17G>C | Intron (SNP) | VAF 17/139 reads (12%) | called by muse, mutect2, varscan2
- RPL38 | c.*15T>C | 3'UTR (SNP) | VAF 26/161 reads (16%) | catalogued as rs775963020; called by muse, mutect2, varscan2
